Surgical pathology report (de-identified scan), TCGA case TCGA-64-5815, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Fox Chase, specimen TCGA-64-5815-01A (Primary Tumor).

[page 1 of 3]
Clinical History/Diagnosis: Lung cancer

Source of Specimen(s):

- 1: Cytology -no fee code
- 2: Level nine lymph nodes
- 3: 10R lymph nodes
- 4: Level seven lymph nodes
- 5: Level 11 lymph node
- 6: Level 11 lymph node at bifurcation of middle and lower lobe
- 7: Right upper and middle lobe

Final Diagnosis:

1. Cytology
2. Level nine lymph nodes, excision:
- No tumor seen in one lymph node (0/1).
3. 10R lymph nodes, excision:
- Metastatic carcinoma in two of two lymph nodes (2/2).
4. Level seven lymph nodes, excision:
- No tumor seen in seven lymph nodes (0/7).
5. Level 11 lymph node, excision:
- No tumor seen in one lymph node (0/1).
6. Level 11 lymph node at bifurcation of middle and lower lobe, excision:
- No tumor seen in one lymph node (0/1).
7. Right upper and middle lobe, resection:
- Invasive poorly differentiated adenosquamous carcinoma, 6.5 cm of the upper lobe.
- Carcinoma invades through visceral pleura.
- Angiolymphatic invasion is not identified.
- Bronchial and vascular margins are free of carcinoma.
- No tumor seen in five parabrachial lymph nodes (0/5).
- pT2 N1 Mx

Gross Description:

Received in seven parts.

Source of Tissue: 1. Cytology

Source of Tissue: 2. Labeled #2, "level 9 lymph nodes"

Gross Description: Received fresh labeled, level 9 lymph nodes". It consists of a firm light-brown lymph node measuring 1.5 x 0.8 x 0.5 cm. The lymph node is bisected and entirely submitted in 2A.

Source of Tissue: 3. Labeled #3, "10R lymph nodes"

[page 2 of 3]
Gross Description: Received fresh labeled ",
10R lymph nodes". It consists of black-brown soft anthracotic lymph nodes
measuring from 1 up to 1.5 cm in greatest dimension. Each lymph node is
bisected and entirely submitted in 3A-3B.

Source of Tissue: 4. Labeled #4, "level 7 lymph nodes"

Gross Description: Received fresh labeled ",
level 7 lymph nodes". It consists of multiple soft black-brown anthracotic
lymph nodes measuring from 0.2 up to 2.0 cm in greatest dimension.
Entirely submitted in 4A-4E.

Designation of Sections: 4A-4B- one large bisected lymph node, 4C- one
bisected lymph node, 4D- two bisected lymph nodes, 4E- multiple small
potential lymph nodes

Source of Tissue: 5. Labeled #5, "level 11 lymph node"

Gross Description: Received fresh labeled ",
level 11 lymph node". It consists of a soft black-brown anthracotic lymph
node measuring 1.2 x 0.5 x 0.5 cm. The lymph node is bisected and entirely
submitted in 5A.

Source of Tissue: 6. Labeled #6, "level 11 lymph node at bifurcation of middle and lower
lobe"

Gross Description: Received fresh labeled,
level 11 lymph node at bifurcation of middle and lower lobe". It consists
of a soft black-brown anthracotic lymph node measuring 0.8 x 0.7 x 0.6 cm.
The lymph node is bisected and entirely submitted in 6A.

Source of Tissue: 7. Labeled #7, "right upper and middle lobe"

Intraoperative Consultation: UPPER LOBE BRONCHIAL MARGIN- NO TUMOR
SEEN PER [REDACTED]

Gross Description: Received fresh labeled ",
right upper and middle lobe". It consists of two lobes of lung weighing a
total of 292 grams. The upper lobe measures 13.5 x 11.5 x 5 cm in greatest
dimension. The pleura is gray-tan, smooth except for a 1.2 cm puckered
area located approximately 6 cm from the closest upper lobe margin and
approximately 4.5 cm from the middle lobe bronchial margin. The middle
lobe measures 10.5 x 10.5 x 4.5 cm. The pleura is gray-tan and smooth.
Both the bronchial margin and vascular margin from both upper and middle
lobes are unremarkable. The upper lobe is sectioned to reveal a 6.5 x 4.5
x 4.5 cm ill-defined firm brown mass located approximately 3.5 cm from the
closest upper lobe bronchial and vascular margins. The mass corresponds to
the previously described pleural puckering of the upper lobe. The middle
lobe is sectioned to reveal a congested soft tan-pink cut surface with no
masses present. The horizontal fissure appears grossly unremarkable. The
upper lobe bronchial margin is entirely frozen in 7FS. Additional random

[page 3 of 3]
sections of the remainder of the specimen are submitted in 7A-7J.

TCGA-64-5815

Designation of Sections: 7FS- frozen section, 7A- right upper lobe
vascular margin, 7B-7D- random section of tumor, 7E- tumor with adjacent
uninvolved parenchyma, 7F- middle lobe bronchial margin, 7G- middle lobe
vascular margin, 7H- horizontal fissure, 7I- uninvolved middle lobe, 7J-
peribronchial lymph nodes

LUNG TEMPLATE

Specimen Type

Right upper and middle lobes

Laterality

Right

Tumor Site

Upper lobe Middle lobe

Tumor Size

Greatest dimension: 6.5 cm (T1 if ≤ 3.0 cm; otherwise T2)

Histologic Type

Adenosquamous carcinoma

Histologic Grade

Poorly differentiated

Extension of Tumor

Carcinoma invades into/through visceral pleura (T2)

Venous (Large Vessel) Invasion

Absent

Arterial (Large Vessel) Invasion

Absent

Margins

Margins uninvolved by invasive carcinoma

Distance from closest margin: 3.5 cm

Regional Lymph Nodes

17 regional lymph nodes examined

Regional lymph node metastasis

2 ipsilateral peribronchial and/or hilar lymph node(s) with
metastatic carcinoma (N1)

pTNM: T2 N1 Mx

Source: NCI Genomic Data Commons file caa09198-0250-4ebe-80b4-831d03c4034f (TCGA-64-5815.D7BEF7C7-2687-4D23-96B2-8DD1F5305997.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).